Somatic mutation profile of tumor specimen MP2PRT-PAPIAC-TMP1-A (aliquot MP2PRT-PAPIAC-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIAC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,848 days).
Specimen MP2PRT-PAPIAC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e60ab942-c39f-44c2-90c4-fa4d1c1b6f45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIAC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIAC-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/978ef096-6c6b-44f2-a25c-e3f9d5fc6337

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 66/262 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AP5S1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 29/395 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs765677394, COSV55694684, COSV99853335; called by muse, mutect2
- ARHGAP23 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 71/984 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs754961345; called by muse, mutect2
- ARL14 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 65/232 reads (28%) | catalogued as rs180925087; called by muse, mutect2, varscan2
- CEACAM16 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200295094; called by muse, mutect2
- CREBBP | c.4308T>A p.S1436R | Missense Mutation (SNP) | VAF 112/231 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52128106, COSV99272893; called by muse, mutect2, varscan2
- LRP1B | c.11936T>G p.V3979G | Missense Mutation (SNP) | VAF 88/332 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV67279902; called by muse, mutect2, varscan2
- MSH4 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV99591579; called by muse, mutect2, varscan2
- RIMS2 | c.3145C>T p.R1049C (on ENST00000666250 / NM_001348490.2; = p.R857C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs774993398, COSV51653273; called by muse, mutect2
- SOX13 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 89/409 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99690056; called by muse, mutect2, varscan2
- ZNF728 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV74099464; called by muse, mutect2, varscan2
- CREBBP | c.4132_4133+4del p.X1378_splice | Splice Site (DEL) | VAF 24/286 reads (8%) | called by mutect2, pindel
- DIS3L2 | c.862_866delinsAGAAGC p.D288Rfs*7 | Frame Shift Ins (INS) | VAF 103/381 reads (27%) | called by pindel, varscan2*
- ENPEP | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GNAT3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- MOGS | c.2344_2345insC p.K782Tfs*5 | Frame Shift Ins (INS) | VAF 152/498 reads (31%) | called by mutect2, pindel*, varscan2
- MYO3B | c.1368G>T p.L456F | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOX1 | c.341_342del p.E114Afs*346 | Frame Shift Del (DEL) | VAF 80/257 reads (31%) | called by pindel*, varscan2
- CD8B | c.201C>T p.H67= | Silent (SNP) | VAF 111/510 reads (22%) | catalogued as rs752467151; called by muse, mutect2, varscan2
- DNAH9 | c.300G>A p.A100= | Silent (SNP) | VAF 171/729 reads (23%) | called by muse, mutect2, varscan2
- HMGB4 | c.138G>A p.S46= | Silent (SNP) | VAF 118/281 reads (42%) | catalogued as rs769820609, COSV99594778; called by muse, mutect2, varscan2
- PIK3R6 | c.1044G>C p.T348= | Silent (SNP) | VAF 121/584 reads (21%) | catalogued as rs764497604; called by muse, mutect2, varscan2
- RHCG | c.393C>T p.C131= | Silent (SNP) | VAF 60/175 reads (34%) | catalogued as rs772870931, COSV51518472; called by muse, mutect2, varscan2
- CFAP410 | c.642+115G>A | Intron (SNP) | VAF 51/1227 reads (4%) | called by muse, mutect2
- RNU6-1178P | chr17:20895996 G>A | 5'Flank (SNP) | VAF 30/416 reads (7%) | catalogued as rs1422357974, COSV60001476; called by muse, mutect2
